Gene-level copy-number profile of tumor specimen REBC-AC91-TTR1-A from REBC case REBC-AC91, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-AC91-TTR1-A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 222129a4-c439-4aab-8dae-aeaeca696093.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-AC91-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/1ec240c1-b343-41db-adb5-79f8d07e3e59

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 1,349; copy number 2: 44,758; copy number 3: 12,260; copy number 4: 24.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:18,178,038–18,345,899, 2 genes: FAM230D, GGTLC5P.
- chr22:18,615,581–18,894,407, 13 genes: Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E, GGT3P, AC008132.2, E2F6P1, AC008132.1, BCRP7, FAM230F, AC008103.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,349. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
